Somatic mutation profile of tumor specimen ALCH-B29X-TTP1-A (aliquot ALCH-B29X-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B29X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.1 years (27,076 days).
Specimen ALCH-B29X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e71e5ff-8b52-43e0-b1dd-b920c832890a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29X-NB1-A (Blood Derived Normal), aliquot ALCH-B29X-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39625f66-01f8-4025-99cd-7ea598a9cc21

The open-access MAF lists 79 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, 5'UTR 2, Splice Site 2, Intron 2, Nonsense Mutation 2, Frame Shift Del 2, 5'Flank 1, RNA 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/332 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2398-1G>T p.X800_splice | Splice Site (SNP) | VAF 69/541 reads (13%) | catalogued as COSV55951359; called by muse, mutect2, varscan2
- ACCSL | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377118963, CM142263; called by muse, mutect2
- CDH6 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 24/209 reads (11%) | catalogued as COSV54069333; called by muse, mutect2, varscan2
- CLCN1 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.616); catalogued as rs746734545, COSV100578257; called by muse, mutect2, varscan2
- COL6A6 | c.5150G>A p.R1717H | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs756792501; called by muse, mutect2, varscan2
- CYP27C1 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs575267325; called by muse, mutect2, varscan2
- DCAF8L1 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as COSV71595400; called by muse, mutect2, varscan2
- MPC2 | c.348-2A>T p.X116_splice | Splice Site (SNP) | VAF 8/112 reads (7%) | catalogued as rs745590496; called by muse, mutect2
- MPP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs369418166; called by muse, mutect2
- MRPL2 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs535875857, COSV54820010; called by muse, mutect2
- NUP210L | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs942003406, COSV55141878; called by muse, mutect2, varscan2
- OR5I1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.602); catalogued as COSV56887899, COSV56889381; called by muse, mutect2, varscan2
- OR8D2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100658962; called by muse, mutect2, varscan2
- RXFP2 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100034590; called by muse, mutect2
- SLC9A3R2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1567352157; called by muse, mutect2
- STK11 | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58820427; called by muse, mutect2
- TREML1 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs778006457, COSV64191092; called by muse, varscan2
- TRIM51 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV99792297; called by muse, mutect2
- XIRP2 | c.6629C>A p.P2210Q (on ENST00000628543; = p.P2385Q on NM_152381.6) | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV54690825; called by muse, mutect2
- ACTN3 | c.812C>G p.T271R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- ADAMTS19 | c.2711C>A p.T904N | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.972); called by muse, mutect2
- ANKRD11 | c.3655G>C p.D1219H | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ARHGEF17 | c.5732A>G p.D1911G | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC73 | c.2165T>A p.L722H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.035); called by muse, mutect2
- CCSER1 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); called by muse, mutect2
- CD40LG | c.133T>A p.Y45N | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDC42BPG | c.3356T>G p.L1119R | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEL | c.803G>T p.G268V (on ENST00000673714; = p.G265V on NM_001807.6) | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- COG5 | c.2103C>T p.F701= (on ENST00000347053 / NM_001379512.1; = p.F722= on NM_006348.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- COL11A2 | c.3613A>G p.N1205D (on ENST00000341947 / NM_080680.3; = p.N1098D on NM_080679.2) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CRTC3 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- EBI3 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.13419G>T p.L4473F | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FUCA1 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GMDS | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2
- GRM6 | c.2453C>A p.T818N | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IL1RAPL1 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 49/531 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- ISLR | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LRWD1 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYO1B | c.2896G>T p.A966S (on ENST00000304164; = p.A908S on NM_012223.5) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- NKX2-1 | c.926_929delinsCA p.G309Afs*99 | Frame Shift Del (DEL) | VAF 27/124 reads (22%) | called by pindel, varscan2*
- OR2AK2 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PGF | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- PTPRT | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SGO2 | c.82A>T p.T28S | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, varscan2
- SHROOM2 | c.4115C>A p.P1372H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A6 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 34/510 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.048); called by muse, mutect2
- ST8SIA2 | c.641T>A p.F214Y | Missense Mutation (SNP) | VAF 48/393 reads (12%) | PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TMEM266 | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- TP53 | c.551_554del p.D184Afs*62 | Frame Shift Del (DEL) | VAF 36/223 reads (16%) | called by mutect2, pindel, varscan2
- TRIM17 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UBR4 | c.6922C>T p.L2308F | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WDR87 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ADAMTS12 | c.4488C>G p.V1496= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- BEND4 | c.438C>G p.A146= | Silent (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
- BRINP1 | c.375C>T p.Y125= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as rs115548564, COSV56299739, COSV56309285; called by muse, mutect2
- CNOT9 | c.678C>T p.A226= | Silent (SNP) | VAF 36/531 reads (7%) | catalogued as COSV55299864; called by muse, mutect2
- DDX21 | c.1059G>A p.V353= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- EEPD1 | c.168G>T p.V56= | Silent (SNP) | VAF 76/392 reads (19%) | called by muse, mutect2, varscan2
- EZHIP | c.1194G>A p.P398= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs782151904; called by muse, mutect2, varscan2
- HOXD11 | c.723C>T p.S241= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1337591401, COSV50911045; called by muse, mutect2
- IRX2 | c.435C>T p.G145= | Silent (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2
- NMUR2 | c.624G>A p.K208= | Silent (SNP) | VAF 14/323 reads (4%) | catalogued as COSV54918705; called by muse, mutect2
- NPHS1 | c.789G>T p.L263= | Silent (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- PIEZO2 | c.513T>C p.D171= | Silent (SNP) | VAF 17/334 reads (5%) | called by muse, mutect2
- RGPD3 | c.36C>T p.V12= | Silent (SNP) | VAF 37/329 reads (11%) | catalogued as rs758246539; called by muse, mutect2, varscan2
- RIMS3 | c.90C>A p.S30= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- RUBCNL | c.45C>G p.P15= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- SALL3 | c.1845G>A p.A615= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs774733461; called by muse, mutect2
- ZNRF4 | c.693G>A p.S231= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs770614237, COSV99706342, COSV99706782; called by muse, mutect2, varscan2
- AL713998.1 | n.154T>C | RNA (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- AMPD2 | c.-28C>A | 5'UTR (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29702371 C>A | 3'Flank (SNP) | VAF 47/549 reads (9%) | catalogued as rs528052606; called by muse, mutect2
- ETFA | c.451+31A>G | Intron (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- KIR2DL3 | c.-20C>A | 5'UTR (SNP) | VAF 47/700 reads (7%) | called by muse, mutect2
- LEMD3 | c.*50T>A | 3'UTR (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- PRDM16 | chr1:3067480 C>A | 5'Flank (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- UGT1A6 | c.862-11981C>A | Intron (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
